Somatic mutation profile of tumor specimen HCM-CSHL-0243-C18-01B (aliquot HCM-CSHL-0243-C18-01B-02D-A78L-36) from HCMI case HCM-CSHL-0243-C18, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Colon, NOS; AJCC pathologic stage: Stage IIA; Tumor grade: G2; Age at diagnosis: 71.9 years (26,279 days).
Specimen HCM-CSHL-0243-C18-01B: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4785fa61-32b2-45a7-a603-d7c32c0c5fa5.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-CSHL-0243-C18-10A (Blood Derived Normal), aliquot HCM-CSHL-0243-C18-10A-01D-A78L-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5f5f4aa9-12eb-434f-ab5c-c03c3b23ded9

The open-access MAF lists 128 somatic variants for this specimen: 89 protein-altering or splice-affecting, 21 silent, 18 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 72, Silent 21, Intron 11, Nonsense Mutation 7, RNA 5, Frame Shift Ins 4, Frame Shift Del 2, Splice Region 2, In Frame Ins 1, 3'UTR 1, In Frame Del 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ATRX | c.599G>T p.C200F | Missense Mutation (SNP) | VAF 54/110 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs886041700, CM062439, CM970153; ClinVar: pathogenic; called by muse, mutect2, varscan2
- FBXW7 | c.1513C>T p.R505C (on ENST00000281708 / NM_001349798.2; = p.R425C on NM_018315.5) | Missense Mutation (SNP) | VAF 169/684 reads (25%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs149680468, COSV55890969, COSV55891274, COSV55898451; ClinVar: likely pathogenic; called by muse, varscan2
- KRAS | c.437C>T p.A146V | Missense Mutation (SNP) | VAF 155/416 reads (37%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen possibly damaging (0.884); catalogued as rs1057519725, COSV55498939; ClinVar: not provided / pathogenic; called by muse, mutect2, varscan2
- ABTB2 | c.1157C>T p.T386M | Missense Mutation (SNP) | VAF 17/46 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs140497119; called by muse, mutect2, varscan2
- AGPAT4 | c.461C>T p.T154M | Missense Mutation (SNP) | VAF 149/572 reads (26%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.78); catalogued as rs781252538, COSV57248906; called by muse, mutect2, varscan2
- ARHGEF2 | c.1460G>A p.R487H (on ENST00000361247 / NM_001162383.2; = p.R459H on NM_004723.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 15/69 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1207479001; called by muse, mutect2, varscan2
- ATRX | c.600C>A p.C200* | Nonsense Mutation (SNP) | VAF 58/115 reads (50%) | catalogued as COSV64878009; called by muse, mutect2, varscan2
- BTNL8 | c.1120G>A p.D374N | Missense Mutation (SNP) | VAF 167/579 reads (29%) | SIFT tolerated (0.56); PolyPhen benign (0.001); catalogued as rs373083701; called by muse, mutect2, varscan2
- CARD9 | c.1078-5G>A | Splice Region (SNP) | VAF 23/71 reads (32%) | catalogued as rs746317918; called by muse, mutect2, varscan2
- CDH18 | c.404C>A p.T135K | Missense Mutation (SNP) | VAF 133/569 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV56922914; called by muse, mutect2, varscan2
- CHDH | c.474G>A p.W158* | Nonsense Mutation (SNP) | VAF 22/92 reads (24%) | catalogued as rs1377660740; called by muse, mutect2, varscan2
- CLSTN2 | c.2566C>T p.R856W | Missense Mutation (SNP) | VAF 76/354 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.723); catalogued as rs199508939, COSV71717984, COSV71725726; called by muse, mutect2, varscan2
- COL6A3 | c.3575G>A p.R1192H | Missense Mutation (SNP) | VAF 68/211 reads (32%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as rs776312405, COSV99796426; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- COL7A1 | c.8776G>A p.E2926K | Missense Mutation (SNP) | VAF 27/83 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.076); catalogued as COSV56476438; called by muse, mutect2, varscan2
- DCLK1 | c.287C>T p.S96L | Missense Mutation (SNP) | VAF 71/271 reads (26%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.975); catalogued as rs750026852, COSV55201416; called by muse, mutect2, varscan2
- DIDO1 | c.4801G>A p.V1601M | Missense Mutation (SNP) | VAF 27/107 reads (25%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.007); catalogued as rs1388945963; called by muse, mutect2, varscan2
- DNAJC10 | c.1082G>A p.R361H | Missense Mutation (SNP) | VAF 110/481 reads (23%) | SIFT tolerated (0.2); PolyPhen benign (0.007); catalogued as rs201121755, COSV51137935; called by muse, varscan2
- EPAS1 | c.2080G>A p.V694M | Missense Mutation (SNP) | VAF 105/381 reads (28%) | SIFT tolerated (0.14); PolyPhen benign (0.003); catalogued as rs375544083, COSV55390884; called by muse, mutect2, varscan2
- EPOP | c.644C>T p.P215L | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.001); catalogued as rs1370451170; called by muse, mutect2, varscan2
- EVL | c.673G>A p.A225T (on ENST00000402714 / NM_001330221.2; = p.A227T on NM_016337.3) | Missense Mutation (SNP) | VAF 16/57 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.769); catalogued as rs201550659; called by muse, mutect2, varscan2
- FAT2 | c.12785G>A p.R4262H | Missense Mutation (SNP) | VAF 30/82 reads (37%) | SIFT tolerated (0.75); PolyPhen benign (0); catalogued as rs750561477, COSV99942932; called by muse, mutect2, varscan2
- GDNF | c.272G>A p.R91Q | Missense Mutation (SNP) | VAF 9/78 reads (12%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.92); catalogued as rs769492137, COSV100427543, COSV58479206; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- GPAM | c.1856C>T p.A619V | Missense Mutation (SNP) | VAF 95/334 reads (28%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.991); catalogued as rs764728397; called by muse, mutect2, varscan2
- KIFC3 | c.923C>T p.A308V | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as rs150167969, COSV65552500; called by muse, mutect2, varscan2
- KRT73 | c.572G>A p.R191Q | Missense Mutation (SNP) | VAF 42/658 reads (6%) | SIFT tolerated (0.15); PolyPhen benign (0.131); catalogued as rs146681578; called by muse, mutect2
- LCE2C | c.108C>A p.C36* | Nonsense Mutation (SNP) | VAF 85/526 reads (16%) | catalogued as COSV100909422; called by muse, mutect2, varscan2
- LPCAT2 | c.1283A>G p.N428S | Missense Mutation (SNP) | VAF 98/359 reads (27%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.867); catalogued as COSV50896204; called by muse, mutect2, varscan2
- MAP6 | c.101C>A p.S34* | Nonsense Mutation (SNP) | VAF 57/206 reads (28%) | catalogued as COSV59075312; called by muse, mutect2, varscan2
- MRM3 | c.775G>A p.A259T | Missense Mutation (SNP) | VAF 29/103 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV58679726; called by muse, mutect2, varscan2
- MROH6 | c.1076G>A p.R359Q | Missense Mutation (SNP) | VAF 54/199 reads (27%) | SIFT tolerated (0.29); PolyPhen probably damaging (0.995); catalogued as rs1455305772, COSV99435356; called by muse, mutect2, varscan2
- MUC12 | c.892C>T p.R298C (on ENST00000379442; = p.R155C on NM_001164462.1) | Missense Mutation (SNP) | VAF 111/380 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.522); catalogued as rs571855490, COSV65198830; called by muse, mutect2, varscan2
- MYO16 | c.4934C>A p.A1645E | Missense Mutation (SNP) | VAF 39/156 reads (25%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.003); catalogued as rs191971963; called by muse, mutect2, varscan2
- NLGN4Y | c.610C>T p.R204C | Missense Mutation (SNP) | VAF 133/227 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52970681, COSV99946191; called by muse, mutect2, varscan2
- NUP133 | c.2143C>T p.P715S | Missense Mutation (SNP) | VAF 53/515 reads (10%) | SIFT tolerated (0.48); PolyPhen benign (0); catalogued as rs1164570532; called by muse, mutect2, varscan2
- PIF1 | c.1589C>T p.T530M | Missense Mutation (SNP) | VAF 75/286 reads (26%) | SIFT tolerated (0.11); PolyPhen benign (0.121); catalogued as rs377317303; called by muse, mutect2, varscan2
- PNPLA2 | c.1176-5C>T | Splice Region (SNP) | VAF 45/151 reads (30%) | catalogued as rs1458057753; called by muse, mutect2, varscan2
- PNPLA7 | c.1196G>A p.R399H | Missense Mutation (SNP) | VAF 40/176 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.031); catalogued as rs145427614; called by muse, mutect2, varscan2
- ROPN1 | c.115G>A p.D39N | Missense Mutation (SNP) | VAF 83/277 reads (30%) | SIFT tolerated (0.09); PolyPhen benign (0.169); catalogued as COSV51739399; called by muse, mutect2, varscan2
- SETD2 | c.5122C>T p.R1708* | Nonsense Mutation (SNP) | VAF 58/242 reads (24%) | catalogued as rs774671060, COSV57449337; called by muse, mutect2, varscan2
- SFT2D1 | c.173C>T p.P58L | Missense Mutation (SNP) | VAF 50/244 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs768482376; called by muse, mutect2, varscan2
- SHANK3 | c.2495C>T p.S832L | Missense Mutation (SNP) | VAF 9/46 reads (20%) | SIFT tolerated (0.41); PolyPhen possibly damaging (0.736); catalogued as rs1287997418; called by muse, mutect2, varscan2
- SPRYD3 | c.997C>T p.R333W | Missense Mutation (SNP) | VAF 31/195 reads (16%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.944); catalogued as rs758900368, COSV56852699; called by muse, mutect2, varscan2
- SQLE | c.506C>T p.P169L | Missense Mutation (SNP) | VAF 52/171 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs747188670, COSV56283201; called by muse, mutect2, varscan2
- SYNE2 | c.12227_12229del p.E4076del | In Frame Del (DEL) | VAF 44/232 reads (19%) | catalogued as rs748493867; called by pindel, varscan2
- SYNE2 | c.14480G>A p.R4827H | Missense Mutation (SNP) | VAF 106/350 reads (30%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as rs774421754, COSV59945467; called by muse, mutect2, varscan2
- TET1 | c.730G>T p.A244S | Missense Mutation (SNP) | VAF 62/271 reads (23%) | SIFT tolerated (0.06); PolyPhen benign (0.142); catalogued as COSV65386962; called by muse, mutect2, varscan2
- TRIM54 | c.505C>T p.R169C | Missense Mutation (SNP) | VAF 55/163 reads (34%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.586); catalogued as rs748843079, COSV56085510; called by muse, mutect2, varscan2
- TRPC7 | c.1951G>A p.V651I | Missense Mutation (SNP) | VAF 113/231 reads (49%) | SIFT tolerated (0.28); PolyPhen benign (0.021); catalogued as rs372192731; called by muse, mutect2, varscan2
- VMO1 | c.446G>A p.G149D | Missense Mutation (SNP) | VAF 62/266 reads (23%) | SIFT tolerated (0.05); PolyPhen benign (0.231); catalogued as COSV54495760; called by muse, mutect2, varscan2
- WFIKKN1 | c.1369G>A p.V457M | Missense Mutation (SNP) | VAF 19/74 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.727); catalogued as rs752283984; called by muse, mutect2, varscan2
- WSCD1 | c.1591C>T p.R531C | Missense Mutation (SNP) | VAF 12/274 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.417); catalogued as rs1394035623, COSV58493531; called by muse, mutect2
- AAK1 | c.1099C>T p.R367C | Missense Mutation (SNP) | VAF 59/198 reads (30%) | SIFT deleterious (0); PolyPhen benign (0); called by muse, mutect2, varscan2
- ADCY5 | c.506C>T p.A169V | Missense Mutation (SNP) | VAF 3/32 reads (9%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0.084); called by muse, mutect2
- APC | c.4089_4093del p.S1364Cfs*9 | Frame Shift Del (DEL) | VAF 69/154 reads (45%) | called by mutect2, pindel, varscan2
- ARMH1 | c.653C>T p.T218I | Missense Mutation (SNP) | VAF 98/392 reads (25%) | SIFT tolerated (0.05); PolyPhen benign (0.054); called by muse, mutect2, varscan2
- ATRIP | c.669_670insCTC p.V223_S224insL | In Frame Ins (INS) | VAF 15/74 reads (20%) | called by pindel, varscan2
- BCL9 | c.1105A>G p.I369V | Missense Mutation (SNP) | VAF 58/384 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- BIRC6 | c.53C>G p.P18R | Missense Mutation (SNP) | VAF 59/255 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.102); called by muse, mutect2, varscan2
- CDH12 | c.1520T>G p.I507S | Missense Mutation (SNP) | VAF 62/275 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- CHM | c.1029G>A p.M343I | Missense Mutation (SNP) | VAF 123/245 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); called by muse, mutect2, varscan2
- CILP2 | c.1459C>T p.P487S | Missense Mutation (SNP) | VAF 20/75 reads (27%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CLIP1 | c.1241G>A p.R414Q | Missense Mutation (SNP) | VAF 59/375 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.298); called by muse, mutect2, varscan2
- CPLANE1 | c.8752_8753dup p.G2920Efs*17 | Frame Shift Ins (INS) | VAF 59/211 reads (28%) | called by mutect2, pindel, varscan2
- DDIAS | c.2130A>C p.E710D | Missense Mutation (SNP) | VAF 60/234 reads (26%) | SIFT tolerated (0.05); PolyPhen benign (0.142); called by muse, mutect2, varscan2
- DHX38 | c.934C>T p.R312W | Missense Mutation (SNP) | VAF 13/70 reads (19%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.613); called by muse, mutect2, varscan2
- DNAH11 | c.3187G>T p.E1063* | Nonsense Mutation (SNP) | VAF 41/164 reads (25%) | called by muse, mutect2, varscan2
- DNAH5 | c.4905A>C p.L1635F | Missense Mutation (SNP) | VAF 121/408 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ELF3 | c.974_975insAT p.Y326Sfs*5 | Frame Shift Ins (INS) | VAF 36/88 reads (41%) | called by mutect2, pindel
- EML6 | c.5637T>A p.N1879K | Missense Mutation (SNP) | VAF 77/259 reads (30%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.576); called by muse, mutect2, varscan2
- GBE1 | c.442del p.S148Vfs*24 | Frame Shift Del (DEL) | VAF 50/216 reads (23%) | called by mutect2, pindel, varscan2
- GIN1 | c.1562T>G p.L521* | Nonsense Mutation (SNP) | VAF 10/43 reads (23%) | called by muse, mutect2, varscan2
- IGSF11 | c.1067C>T p.S356F (on ENST00000393775 / NM_001015887.3; = p.S355F on NM_152538.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 92/414 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.1); called by muse, mutect2, varscan2
- KRT27 | c.212C>A p.A71D | Missense Mutation (SNP) | VAF 63/202 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.15); called by muse, mutect2, varscan2
- LUZP2 | c.578A>G p.E193G | Missense Mutation (SNP) | VAF 56/268 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- MED26 | c.1276A>C p.T426P | Missense Mutation (SNP) | VAF 37/156 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- NELL2 | c.1126G>T p.A376S | Missense Mutation (SNP) | VAF 81/562 reads (14%) | SIFT tolerated (0.14); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- NOTCH4 | c.2813C>T p.P938L | Missense Mutation (SNP) | VAF 161/306 reads (53%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- NPLOC4 | c.763C>T p.R255W | Missense Mutation (SNP) | VAF 99/323 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- OVOL3 | c.485G>A p.R162H (on ENST00000585332; = p.R138H on NM_001302757.1) | Missense Mutation (SNP) | VAF 32/156 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.732); called by muse, mutect2, varscan2
- PDIA6 | c.905dup p.P303Afs*5 | Frame Shift Ins (INS) | VAF 38/156 reads (24%) | called by mutect2, pindel, varscan2
- PFKFB2 | c.487G>A p.V163I | Missense Mutation (SNP) | VAF 92/610 reads (15%) | PolyPhen benign (0.025); called by muse, mutect2, varscan2
- PITPNM2 | c.1014T>G p.D338E | Missense Mutation (SNP) | VAF 37/231 reads (16%) | SIFT tolerated (1); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- PKP1 | c.89A>G p.K30R | Missense Mutation (SNP) | VAF 134/833 reads (16%) | SIFT tolerated (0.26); PolyPhen benign (0); called by muse, mutect2, varscan2
- PPP1R13B | c.8C>T p.P3L | Missense Mutation (SNP) | VAF 14/78 reads (18%) | SIFT tolerated (0.06); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- SDK1 | c.2032C>T p.P678S | Missense Mutation (SNP) | VAF 84/325 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- SETD2 | c.6584_6588dup p.V2197Tfs*53 | Frame Shift Ins (INS) | VAF 95/460 reads (21%) | called by mutect2, pindel, varscan2
- TALDO1 | c.286C>A p.L96I | Missense Mutation (SNP) | VAF 96/371 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); called by muse, mutect2, varscan2
- TTN | c.93012T>A p.H31004Q (on ENST00000591111; = p.H23580Q on NM_003319.4) | Missense Mutation (SNP) | VAF 60/260 reads (23%) | PolyPhen benign (0.021); called by muse, mutect2, varscan2
- ZCRB1 | c.177G>C p.L59F | Missense Mutation (SNP) | VAF 56/366 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.277); called by muse, mutect2, varscan2
- ADGRL2 | c.1233T>G p.A411= | Silent (SNP) | VAF 58/206 reads (28%) | called by muse, mutect2
- AMELY | c.534C>T p.P178= (on ENST00000383036 / NM_001364814.1; = p.P164= on NM_001143.1) | Silent (SNP) | VAF 59/97 reads (61%) | called by muse, mutect2, varscan2
- ARID4A | c.3138A>G p.A1046= | Silent (SNP) | VAF 25/135 reads (19%) | called by muse, mutect2, varscan2
- CGAS | c.1098A>G p.E366= | Silent (SNP) | VAF 42/138 reads (30%) | called by muse, mutect2, varscan2
- CLMN | c.2319G>A p.E773= | Silent (SNP) | VAF 20/80 reads (25%) | called by muse, mutect2, varscan2
- EMILIN1 | c.2406C>T p.D802= | Silent (SNP) | VAF 9/29 reads (31%) | catalogued as rs1188315768; called by muse, mutect2
- FAM83G | c.306C>T p.S102= | Silent (SNP) | VAF 18/57 reads (32%) | called by muse, mutect2, varscan2
- FUT5 | c.600G>A p.S200= | Silent (SNP) | VAF 43/214 reads (20%) | catalogued as rs755502536, COSV53138682; called by muse, mutect2, varscan2
- INPP5D | c.1470C>T p.I490= (on ENST00000445964 / NM_001017915.3; = p.I489= on NM_005541.5) | Silent (SNP) | VAF 18/96 reads (19%) | catalogued as rs201454690; called by muse, mutect2, varscan2
- MUC16 | c.13119C>A p.P4373= | Silent (SNP) | VAF 25/110 reads (23%) | called by muse, mutect2, varscan2
- OPCML | c.327C>T p.D109= | Silent (SNP) | VAF 55/248 reads (22%) | catalogued as rs144949245; called by muse, mutect2, varscan2
- PCDHB7 | c.1209G>C p.L403= | Silent (SNP) | VAF 44/172 reads (26%) | called by muse, mutect2, varscan2
- PCDHGB7 | c.1332C>T p.D444= | Silent (SNP) | VAF 30/141 reads (21%) | called by muse, varscan2
- PRKG1 | c.1281C>T p.I427= | Silent (SNP) | VAF 54/201 reads (27%) | catalogued as rs868492323; called by muse, mutect2, varscan2
- RRAD | c.888C>T p.R296= | Silent (SNP) | VAF 14/56 reads (25%) | called by muse, mutect2
- RYR3 | c.2673C>T p.F891= | Silent (SNP) | VAF 43/173 reads (25%) | catalogued as rs1018585519; called by muse, mutect2, varscan2
- SLIT3 | c.1107G>A p.E369= | Silent (SNP) | VAF 59/261 reads (23%) | called by muse, mutect2, varscan2
- SUGCT | c.976T>C p.L326= | Silent (SNP) | VAF 87/273 reads (32%) | catalogued as rs923708159; called by muse, mutect2, varscan2
- TRPA1 | c.1374T>C p.R458= | Silent (SNP) | VAF 103/453 reads (23%) | catalogued as rs771776111; called by muse, mutect2, varscan2
- WWC1 | c.2022A>G p.Q674= | Silent (SNP) | VAF 70/290 reads (24%) | called by muse, mutect2, varscan2
- ZNF93 | c.969G>A p.K323= | Silent (SNP) | VAF 38/176 reads (22%) | catalogued as rs765870925; called by muse, mutect2, varscan2
- ABCG1 | c.1808+26G>A | Intron (SNP) | VAF 30/143 reads (21%) | catalogued as rs2276234; called by muse, mutect2, varscan2
- B3GALT5-AS1 | n.1068C>T | RNA (SNP) | VAF 41/254 reads (16%) | called by muse, mutect2, varscan2
- C5orf17 | n.236C>G | RNA (SNP) | VAF 9/19 reads (47%) | catalogued as rs544513975; called by muse, mutect2, varscan2
- DLG2 | c.205-21860G>A | Intron (SNP) | VAF 38/120 reads (32%) | catalogued as rs755938527; called by muse, mutect2, varscan2
- FOXP2 | c.*1591T>G | 3'UTR (SNP) | VAF 108/455 reads (24%) | called by muse, mutect2, varscan2
- LINC01511 | n.437-8480C>T | Intron (SNP) | VAF 9/64 reads (14%) | catalogued as rs892007098; called by muse, mutect2, varscan2
- LY9 | c.1072+29C>A | Intron (SNP) | VAF 20/80 reads (25%) | called by muse, mutect2, varscan2
- LYRM4 | c.208-34723C>T | Intron (SNP) | VAF 63/316 reads (20%) | catalogued as rs1326669740; called by muse, mutect2, varscan2
- NORAD | n.490G>T | RNA (SNP) | VAF 34/145 reads (23%) | called by muse, mutect2, varscan2
- NPIPB14P | n.140C>G | RNA (SNP) | VAF 84/369 reads (23%) | catalogued as rs772162065; called by muse, mutect2, varscan2
- PDXK | c.88-1615G>A | Intron (SNP) | VAF 118/437 reads (27%) | catalogued as rs752593956; called by muse, mutect2, varscan2
- PIP5K1C | c.1920+1510C>T | Intron (SNP) | VAF 32/110 reads (29%) | catalogued as rs1365312688; called by muse, varscan2
- RORA | c.196+51377G>C | Intron (SNP) | VAF 64/243 reads (26%) | catalogued as COSV55037446, COSV55042395; called by muse, mutect2, varscan2
- RPN2 | c.-21C>T | 5'UTR (SNP) | VAF 16/93 reads (17%) | catalogued as rs1328084199; called by muse, mutect2, varscan2
- SNURFL | n.279G>A | RNA (SNP) | VAF 36/65 reads (55%) | catalogued as rs759760357; called by muse, mutect2, varscan2
- TTC19 | c.995-18C>A | Intron (SNP) | VAF 62/309 reads (20%) | called by muse, mutect2, varscan2
- Z96074.1 | n.151+3135C>A | Intron (SNP) | VAF 28/52 reads (54%) | called by muse, mutect2, varscan2
- ZNF496 | c.651+453C>T | Intron (SNP) | VAF 46/311 reads (15%) | catalogued as rs1309991710, COSV54174282; called by muse, mutect2, varscan2
